Somatic mutation profile of tumor specimen MP2PRT-PAVHYF-TBP1-A (aliquot MP2PRT-PAVHYF-TBP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVHYF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,340 days).
Specimen MP2PRT-PAVHYF-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a17eb2e-b2ba-46b3-accd-a8f3828601ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVHYF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVHYF-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33ea7898-decb-4371-b80f-e2c2b7fc1ceb

The open-access MAF lists 15 somatic variants for this specimen: 8 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 6, Missense Mutation 6, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 123/395 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CAMK4 | c.536C>A p.A179E | Missense Mutation (SNP) | VAF 81/316 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100000397; called by muse, mutect2, varscan2
- LYPLAL1 | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 124/495 reads (25%) | catalogued as rs775363916, COSV100859690; called by muse, mutect2, varscan2
- MYH14 | c.10G>A p.V4M | Missense Mutation (SNP) | VAF 134/441 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs532458856, COSV51836643; called by muse, mutect2, varscan2
- PAX5 | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 147/482 reads (30%) | catalogued as rs377685637, COSV63911660; called by muse, mutect2, varscan2
- TRPC6 | c.1222C>T p.L408F | Missense Mutation (SNP) | VAF 154/459 reads (34%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as COSV60259482; called by muse, mutect2, varscan2
- USH1G | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 113/511 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as rs775117744, COSV58882007; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACSM4 | c.1684A>G p.T562A | Missense Mutation (SNP) | VAF 66/201 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ANKFN1 | c.3261C>T p.P1087= (on ENST00000653862; = p.P940= on NM_001365758.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 146/657 reads (22%) | catalogued as COSV101633447; called by muse, mutect2, varscan2
- APBB2 | c.75C>T p.D25= | Silent (SNP) | VAF 92/459 reads (20%) | catalogued as rs1338321948; called by muse, mutect2, varscan2
- PITPNM3 | c.1566C>T p.S522= | Silent (SNP) | VAF 42/807 reads (5%) | catalogued as rs1020154569; called by muse, mutect2
- SPTBN2 | c.3534G>T p.L1178= | Silent (SNP) | VAF 128/389 reads (33%) | called by muse, mutect2, varscan2
- TACC2 | c.3720C>A p.V1240= | Silent (SNP) | VAF 106/370 reads (29%) | catalogued as COSV100551888, COSV100554014; called by muse, mutect2, varscan2
- UXS1 | c.948C>T p.N316= | Silent (SNP) | VAF 107/323 reads (33%) | catalogued as rs748522365; called by muse, mutect2, varscan2
- GABRG3 | c.712+46C>A | Intron (SNP) | VAF 85/244 reads (35%) | called by muse, mutect2, varscan2
